Somatic mutation profile of tumor specimen TCGA-DU-5870-02A (aliquot TCGA-DU-5870-02A-12D-A36O-08) from TCGA case TCGA-DU-5870, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 34.9 years (12,764 days).
Specimen TCGA-DU-5870-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b32d09d5-a07a-4c47-929c-d18463bd0fe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5870-10A (Blood Derived Normal), aliquot TCGA-DU-5870-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41ca1e91-fb5f-4118-9a5e-d8572effba24

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Nonsense Mutation 3, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 17/26 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APBA2 | c.382C>G p.P128A | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as COSV101382127; called by muse, mutect2, varscan2
- B4GALNT2 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs372897714; called by muse, mutect2, varscan2
- CCL3 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771827521; called by muse, mutect2, varscan2
- CD109 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as rs200340875, COSV54659231; called by muse, mutect2, varscan2
- EIF2S3 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99450803; called by muse, mutect2, varscan2
- ELK1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99902025; called by muse, mutect2, varscan2
- FOXK1 | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61067837; called by muse, mutect2, varscan2
- FRMPD3 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as COSV99346149; called by muse, mutect2
- HELZ2 | c.3413C>T p.T1138I (on ENST00000467148 / NM_001037335.2; = p.T569I on NM_033405.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1169018489, COSV100915544; called by muse, mutect2, varscan2
- HELZ2 | c.3412A>T p.T1138S (on ENST00000467148 / NM_001037335.2; = p.T569S on NM_033405.3) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV100915545; called by muse, mutect2, varscan2
- KIAA0100 | c.4744A>G p.N1582D | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101197285; called by muse, mutect2, varscan2
- KSR2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs1354361499, COSV100348399; called by muse, mutect2
- MAP3K12 | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99913189; called by muse, mutect2, varscan2
- OR4B1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs773802995, COSV100535573; called by muse, mutect2, varscan2
- PRAMEF4 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 47/101 reads (47%) | catalogued as rs1349449225, COSV99339721; called by muse, mutect2, varscan2
- PSG3 | c.457A>G p.S153G | Missense Mutation (SNP) | VAF 102/130 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV100548898; called by muse, mutect2, varscan2
- RSPO2 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1249794255, COSV99409419; called by muse, mutect2, varscan2
- SCN7A | c.4280T>A p.L1427H | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101313175; called by muse, mutect2, varscan2
- SEC16A | c.1595G>C p.R532T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV99257454; called by muse, mutect2, varscan2
- SLFN12 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as rs143225670; called by muse, mutect2, varscan2
- SUCLA2 | c.890A>T p.N297I (on ENST00000643023; = p.N276I on NM_003850.3) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV101074808; called by muse, mutect2, varscan2
- TBC1D15 | c.1942G>T p.V648F | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV100041669; called by muse, mutect2, varscan2
- TLR2 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV52605731, COSV99472258; called by muse, mutect2, varscan2
- TRMT10A | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV56745820; called by muse, mutect2, varscan2
- UQCC1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs758084857, COSV100568495; called by muse, mutect2, varscan2
- ZFYVE26 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs770457525, COSV100720323; called by muse, mutect2
- DNAJC8 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGA | c.599A>C p.Y200S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNRNP48 | c.239del p.L80* | Frame Shift Del (DEL) | VAF 39/105 reads (37%) | called by mutect2, pindel, varscan2
- TCF12 | c.1216_1217insTCTA p.R406Ifs*2 | Frame Shift Ins (INS) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- CRX | c.450A>T p.S150= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99704429; called by muse, mutect2
- ELK1 | c.858G>C p.L286= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99902032; called by muse, mutect2, varscan2
- MAGEB6 | c.802C>T p.L268= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as COSV100983721; called by muse, mutect2, varscan2
- OR2M5 | c.570T>C p.N190= | Silent (SNP) | VAF 19/345 reads (6%) | catalogued as COSV63546773; called by muse, mutect2
- OR2M7 | c.570T>C p.N190= | Silent (SNP) | VAF 144/340 reads (42%) | catalogued as COSV100522512; called by muse, mutect2, varscan2
- PPP1R3A | c.291C>T p.D97= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs1252722268, COSV99492646; called by muse, mutect2, varscan2
- PRAMEF4 | c.1413G>C p.L471= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV99339724; called by muse, mutect2, varscan2
- SMARCC2 | c.1651-296T>G | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99911194; called by muse, mutect2, varscan2
